Somatic mutation profile of tumor specimen 0DX5CB from CCDI case PBCPYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 8.5 years (3,122 days).
Specimen 0DX5CB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 231bae50-bab8-4109-8122-eeac77ac2bcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX5C9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f4608b7-2cc4-4e58-89bf-862a6ad6ca78

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Intron 6, 3'UTR 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG1L2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs752797458, COSV70648925; called by muse, varscan2
- CERCAM | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as rs372372318; called by muse, varscan2
- GJA1 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 108/470 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV56997437; called by muse, varscan2
- IQCA1 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 84/573 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1476647968; called by muse, varscan2
- KLHDC1 | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 126/488 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63779153; called by muse, varscan2
- PBK | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 160/650 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1563494371; called by muse, varscan2
- SNX6 | c.970C>G p.R324G (on ENST00000652385; = p.R196G on NM_021249.5) | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV104422183; called by muse, varscan2
- STXBP2 | c.1329G>C p.Q443H | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1241867959; called by muse, varscan2
- ABCC3 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 171/780 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- ADAMTS19 | c.1705T>G p.Y569D | Missense Mutation (SNP) | VAF 181/559 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADCY4 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 184/344 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.278); called by muse, varscan2
- BEND5 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 218/830 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.439); called by muse, varscan2
- CFTR | c.4368C>A p.S1456R | Missense Mutation (SNP) | VAF 200/1417 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.562); called by muse, varscan2
- CHD4 | c.2082+1G>T p.X694_splice (on ENST00000357008 / NM_001363606.2; = p.X707_splice on NM_001273.5) | Splice Site (SNP) | VAF 111/422 reads (26%) | called by muse, varscan2
- DCDC2 | c.924T>A p.D308E | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, varscan2
- DCDC2 | c.923A>C p.D308A | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, varscan2
- DEPDC5 | c.2404C>T p.P802S (on ENST00000400246; = p.P871S on NM_014662.5) | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- DHDH | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, varscan2
- FCRL5 | c.2661-3C>A | Splice Region (SNP) | VAF 110/426 reads (26%) | called by muse, varscan2
- FER1L5 | c.3949T>A p.S1317T (on ENST00000623019; = p.S1290T on NM_001293083.2) | Missense Mutation (SNP) | VAF 116/541 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- GAL3ST3 | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- GLYATL1B | c.720G>C p.R240S | Missense Mutation (SNP) | VAF 140/480 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, varscan2
- HJV | c.489del p.F164Sfs*82 (on ENST00000336751 / NM_213653.4; = p.F51Sfs*82 on NM_145277.5) | Frame Shift Del (DEL) | VAF 98/396 reads (25%) | called by pindel, varscan2
- IGF1R | c.2653T>C p.Y885H | Missense Mutation (SNP) | VAF 131/550 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, varscan2
- ISLR2 | c.1544G>C p.G515A | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, varscan2
- KREMEN1 | c.403A>G p.T135A (on ENST00000407188; = p.T137A on NM_032045.5) | Missense Mutation (SNP) | VAF 178/688 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, varscan2
- RWDD1 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 195/699 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, varscan2
- SCN1A | c.3046G>C p.V1016L (on ENST00000303395 / NM_001202435.3; = p.V1005L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/777 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.03); called by muse, varscan2
- SKAP2 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.712); called by muse, varscan2
- SOX3 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); called by muse, varscan2
- TBC1D22B | c.499A>T p.I167F | Missense Mutation (SNP) | VAF 164/700 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, varscan2
- TBX21 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); called by muse, varscan2
- TTN | c.22307A>C p.K7436T (on ENST00000591111; = p.K6509T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/535 reads (25%) | PolyPhen possibly damaging (0.736); called by muse, varscan2
- XYLT2 | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 90/498 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); called by muse, varscan2
- ZNF462 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 62/508 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- ANXA5 | c.825C>T p.S275= | Silent (SNP) | VAF 84/862 reads (10%) | called by muse, varscan2
- CCDC85A | c.738G>A p.P246= | Silent (SNP) | VAF 68/250 reads (27%) | catalogued as rs757126869; called by muse, varscan2
- GAS7 | c.993C>T p.S331= (on ENST00000432992 / NM_201433.2; = p.S191= on NM_003644.3) | Silent (SNP) | VAF 110/597 reads (18%) | catalogued as COSV60431753, COSV60441354; called by muse, varscan2
- PRKG2 | c.1518G>A p.E506= | Silent (SNP) | VAF 100/507 reads (20%) | called by muse, varscan2
- TACR3 | c.99C>T p.A33= | Silent (SNP) | VAF 67/247 reads (27%) | called by muse, varscan2
- TBC1D8B | c.1617T>C p.S539= | Silent (SNP) | VAF 162/248 reads (65%) | called by muse, varscan2
- TNXB | c.11133T>C p.S3711= (on ENST00000647633; = p.S3464= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/354 reads (25%) | called by muse, varscan2
- ADORA2B | c.*75G>T | 3'UTR (SNP) | VAF 46/194 reads (24%) | called by muse, varscan2
- CATSPERG | c.469+53G>T | Intron (SNP) | VAF 44/152 reads (29%) | called by muse, varscan2
- CPNE9 | c.109+27G>A | Intron (SNP) | VAF 94/284 reads (33%) | called by muse, varscan2
- ERFE | c.887+89C>T | Intron (SNP) | VAF 14/53 reads (26%) | called by muse, varscan2
- MTARC2 | c.*79_*80del | 3'UTR (DEL) | VAF 112/562 reads (20%) | called by pindel, varscan2
- NSUN5 | c.755+93C>G | Intron (SNP) | VAF 47/126 reads (37%) | catalogued as rs1175221169; called by muse, varscan2
- PDLIM1 | c.534-25T>A | Intron (SNP) | VAF 100/339 reads (29%) | called by muse, varscan2
- UXT | c.249-35C>G | Intron (SNP) | VAF 88/130 reads (68%) | called by muse, varscan2
